Somatic mutation profile of tumor specimen TARGET-30-PASNZU-01A (aliquot TARGET-30-PASNZU-01A-01D) from TARGET case TARGET-30-PASNZU, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 3.0 years (1,099 days).
Specimen TARGET-30-PASNZU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 919a7b8b-855a-4887-a2fc-96e33e150660.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASNZU-10A (Blood Derived Normal), aliquot TARGET-30-PASNZU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31cb4cb2-f2a0-4db7-8b92-485bea5ee393

The open-access MAF lists 24 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 5, Intron 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDK10 | c.572C>A p.P191Q (on ENST00000353379 / NM_052988.5; = p.P120Q on NM_052987.4) | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV57048528; called by muse, mutect2, varscan2
- CPT1B | c.1849C>A p.Q617K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs370319926; called by muse, mutect2, varscan2
- DCHS1 | c.6925C>A p.L2309M | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV55041473; called by muse, mutect2, varscan2
- FUT10 | c.204G>T p.L68F | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.343); catalogued as COSV59453815; called by muse, mutect2, varscan2
- HSD17B1 | c.79C>A p.P27T | Missense Mutation (SNP) | VAF 43/66 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.367); catalogued as COSV56798512; called by muse, mutect2, varscan2
- KDR | c.754C>A p.L252I | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as COSV55774054; called by muse, mutect2, varscan2
- NOTCH3 | c.5065G>T p.G1689C | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.76); catalogued as COSV54646776; called by muse, mutect2, varscan2
- OPALIN | c.98C>A p.A33E | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100959551, COSV64520885; called by muse, varscan2
- OR2W1 | c.749T>G p.M250R | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV65851856; called by muse, mutect2, varscan2
- PCDHB5 | c.319C>A p.Q107K | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV50665407; called by muse, mutect2, varscan2
- PSPH | c.269G>A p.G90D | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs868557218; called by muse, mutect2
- ZNF208 | c.1150C>A p.L384I | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV68111539; called by muse, mutect2, varscan2
- ZNF560 | c.1862G>T p.R621I | Missense Mutation (SNP) | VAF 56/104 reads (54%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs775205901, COSV56870961; called by muse, mutect2, varscan2
- HOXB1 | c.405_435del p.P136Tfs*38 | Frame Shift Del (DEL) | VAF 43/83 reads (52%) | called by mutect2, pindel
- HYDIN | c.10057C>A p.Q3353K | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MAP1A | c.3273G>T p.L1091F | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.803); called by muse, mutect2
- MRC1 | c.929C>A p.A310D | Missense Mutation (SNP) | VAF 98/218 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- ATP12A | c.1161C>A p.I387= | Silent (SNP) | VAF 25/50 reads (50%) | catalogued as COSV54521728; called by muse, mutect2, varscan2
- CUBN | c.8577A>G p.Q2859= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as COSV64724983; called by muse, mutect2, varscan2
- MAN2A2 | c.318C>A p.P106= | Silent (SNP) | VAF 62/181 reads (34%) | catalogued as COSV64639630; called by muse, mutect2, varscan2
- USP54 | c.3057C>A p.G1019= | Silent (SNP) | VAF 43/49 reads (88%) | catalogued as COSV60446762; called by muse, mutect2, varscan2
- ZNF462 | c.5211C>T p.S1737= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs757049518, COSV52930148; called by muse, mutect2, varscan2
- MASP1 | c.1303+5692C>A | Intron (SNP) | VAF 4/32 reads (13%) | called by mutect2, varscan2
- TMEM99 | n.1004C>A | RNA (SNP) | VAF 20/71 reads (28%) | catalogued as COSV56985123; called by muse, mutect2, varscan2
